CPTAC case C3L-00095 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/84ccbb07-5434-47e2-ba17-57d64331b8e2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 62.6 years (22,863 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,794 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,794 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.4 cm (a second GDC size field records 4 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 13; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 399 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 1,021 days (2.8 years); Disease response: Tumor Free.
- Days to follow up: 1,427 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,794 days (4.9 years); Disease response: Complete Response.
- Days to follow up: 1,794 days (4.9 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 677.

Other clinical attributes
- Weight: 106 kg; Height: 175 cm; BMI: 34.61; Comorbidities: Anxiety; Diabetes treatment type: Insulin; DLCO (% of predicted): 91; FEV1/FVC after bronchodilator (%): 60; FEV1/FVC before bronchodilator (%): 67; FEV1 after bronchodilator (% of reference): 65; FEV1 before bronchodilator (% of reference): 65.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 25; Cigarettes per day: 10; Tobacco smoking onset year: 1965; Exposure duration years: 57.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00095-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 222 mg; Time between excision and freezing: 21 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00095-21: Section location: Left Upper Lobe; Percent tumor nuclei: 70; Percent necrosis: 0.
- Sample C3L-00095-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 202 mg.
- Sample C3L-00095-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 220 mg.
- Sample C3L-00095-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 500 mg; Time between excision and freezing: 21 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00095-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
